Somatic mutation profile of tumor specimen TCGA-ZN-A9VV-01A (aliquot TCGA-ZN-A9VV-01A-11D-A39R-32) from TCGA case TCGA-ZN-A9VV, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 68.7 years (25,096 days).
Specimen TCGA-ZN-A9VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 576bfd7d-26e9-4daf-acf7-cd87ff61c1e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZN-A9VV-10A (Blood Derived Normal), aliquot TCGA-ZN-A9VV-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a341aed8-1a6d-4032-92df-e916220f4377

The open-access MAF lists 35 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Frame Shift Del 6, Silent 4, Nonsense Mutation 3, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCM2 | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs145734072; called by muse, mutect2, varscan2
- ESPN | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs771971308, COSV64704680; called by muse, mutect2, varscan2
- GUCY1A2 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1054998865, COSV56477596; called by muse, mutect2, varscan2
- HNF4G | c.53G>T p.R18I (on ENST00000354370 / NM_001330561.2; = p.R65I on NM_004133.5) | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100584523; called by muse, mutect2, varscan2
- ITGB7 | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1238309807; called by muse, mutect2, varscan2
- ITIH1 | c.725A>T p.Q242L | Missense Mutation (SNP) | VAF 91/104 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs758842033; called by muse, mutect2, varscan2
- NF2 | c.459del p.Y153* | Frame Shift Del (DEL) | VAF 49/90 reads (54%) | catalogued as CM001735, CM045464, COSV58521663, COSV58523049, COSV58526214; called by mutect2, pindel, varscan2
- PRAMEF7 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs753498862, COSV100435111; called by muse, mutect2, varscan2
- PTCH1 | c.3058del p.Q1020Sfs*29 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | catalogued as CM112677, COSV59474705; called by mutect2, pindel, varscan2
- PTCH1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as COSV59464756; called by muse, mutect2
- SETD2 | c.6715C>T p.Q2239* | Nonsense Mutation (SNP) | VAF 86/105 reads (82%) | catalogued as COSV100340129; called by muse, mutect2, varscan2
- THEMIS | c.1798C>G p.Q600E | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100965449; called by muse, mutect2, varscan2
- AC005324.2 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); called by muse, mutect2
- BAP1 | c.876_897del p.P293Gfs*35 | Frame Shift Del (DEL) | VAF 17/22 reads (77%) | called by mutect2, pindel, varscan2
- CLINT1 | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL27A1 | c.983C>G p.S328* | Nonsense Mutation (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- DLGAP2 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNALI1 | c.794A>G p.N265S (on ENST00000296218; = p.N243S on NM_003462.5) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- FANCA | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- FBN3 | c.6134del p.P2045Lfs*41 | Frame Shift Del (DEL) | VAF 129/313 reads (41%) | called by mutect2, pindel, varscan2
- FBN3 | c.2606-2A>G p.X869_splice | Splice Site (SNP) | VAF 66/161 reads (41%) | called by muse, mutect2, varscan2
- IQCF2 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 94/111 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MOBP | c.494T>G p.L165R (on ENST00000420739; = p.L189R on NM_001278322.2) | Missense Mutation (SNP) | VAF 84/174 reads (48%) | PolyPhen benign (0.127); called by muse, varscan2
- NCKAP1L | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHACTR3 | c.91_95del p.S31Rfs*9 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- SETX | c.1148A>T p.Y383F | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UTP4 | c.1652T>C p.F551S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- WNT3 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 145/334 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF175 | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF431 | c.788_794del p.E263Vfs*16 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, varscan2
- GPBP1L1 | c.1125G>T p.V375= | Silent (SNP) | VAF 52/153 reads (34%) | catalogued as rs914062055; called by muse, mutect2, varscan2
- NXPE4 | c.360G>T p.L120= | Silent (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.2217A>C p.T739= | Silent (SNP) | VAF 72/170 reads (42%) | called by muse, mutect2, varscan2
- VARS2 | c.765G>A p.V255= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as COSV52561328; called by muse, mutect2, varscan2
- FGFR3 | c.*255G>A | 3'UTR (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
